TCGA case TCGA-C5-A3HF — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/085df27c-9bc2-425a-9a49-547d692ea028

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 24 years; Vital status: Dead; Days to death: 543 days (1.5 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Mucinous adenocarcinoma, endocervical type (the primary disease): ICD-O-3 morphology code: 8482/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 25.0 years (9,115 days); Year of diagnosis: 1996; Method of diagnosis: Biopsy; FIGO stage: Stage IB2; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 11; Lymph nodes tested: 32.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Treatment given: Treatment type: Radiation, Combination; Treatment intent type: Adjuvant; Days to treatment start: 57 days; Days to treatment end: 101 days; Treatment dose: 5,040 cGy; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Metastasis of diagnosis 1 (Mucinous adenocarcinoma, endocervical type), site: Pelvis, NOS. Age at diagnosis: 26.2 years (9,565 days); Days to diagnosis: 450 days (1.2 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 450 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 450 days (1.2 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 543 days (1.5 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 9; Age at onset: 16.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A3HF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-C5-A3HF-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 65; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-C5-A3HF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A3HF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 1; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 1; Tobacco smoking history indicator: 2; Submitted tumor site: Cervical; Histologic diagnosis: Mucinous Adenocarcinoma of Endocervical Type; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator); Pos lymph node location: Para-aortic.
- Follow-up form: Tumor status: With tumor; Cause of death: Cervical Cancer; Treatment outcome at TCGA followup: Progressive Disease; Radiation adjuvant indicator: Yes; Brachytherapy type: HDR; Days to brachytherapy begin occurrence: 71; Days to brachytherapy end occurrence: 88; Brachytherapy status: Completed as planned; Radiation therapy xrt type: External beam radiation; New tumor event type: Distant Metastasis; New tumor event site other: Pelvis; New tumor event surgery: CT; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form, Radiation supplemental: Radiation therapy status: Completed as Planned; Chemo concurrent reason not given: Not done per treating physicians discretion.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 543 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 543 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 450 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A3HF-01A-11D-A20T-01): tumor purity 0.42, ploidy 2.07, whole-genome doublings 0.
